Somatic mutation profile of tumor specimen TCGA-BR-A4IV-01A (aliquot TCGA-BR-A4IV-01A-31D-A25D-08) from TCGA case TCGA-BR-A4IV, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Carcinoma, diffuse type; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 48.0 years (17,515 days).
Specimen TCGA-BR-A4IV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4ec86d58-dfb4-4f9f-8e9f-ee503afbcd7e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BR-A4IV-10A (Blood Derived Normal), aliquot TCGA-BR-A4IV-10A-01D-A25E-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be0dbe96-5f29-4d4c-9166-c1e57dcdd84d

The open-access MAF lists 16 somatic variants for this specimen: 10 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDH1 | c.760G>T p.D254Y | Missense Mutation (SNP) | VAF 14/174 reads (8%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1555515445, CM1511046, COSV55727198, COSV55729198, COSV55735587; ClinVar: pathogenic; called by muse, mutect2
- CA8 | c.135T>A p.N45K | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.995); catalogued as COSV58770437, COSV58771712; called by muse, mutect2
- DDX53 | c.1815G>C p.K605N | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.133); catalogued as COSV60068888; called by muse, mutect2, varscan2
- HAS2 | c.811C>T p.Q271* | Nonsense Mutation (SNP) | VAF 9/112 reads (8%) | catalogued as COSV100392072, COSV58263497; called by muse, mutect2
- NME8 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.673); catalogued as COSV52246381; called by muse, mutect2
- OR10K1 | c.266A>C p.K89T | Missense Mutation (SNP) | VAF 9/191 reads (5%) | SIFT tolerated (0.55); PolyPhen benign (0.354); catalogued as rs956731453, COSV56871114; called by muse, mutect2
- REN | c.1153T>A p.F385I | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65817657; called by muse, mutect2, varscan2
- RHOA | c.179C>A p.T60K | Missense Mutation (SNP) | VAF 13/112 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV69042310; called by muse, mutect2, varscan2
- SPTA1 | c.3258A>T p.L1086F | Missense Mutation (SNP) | VAF 7/111 reads (6%) | SIFT tolerated (0.7); PolyPhen benign (0.007); catalogued as COSV63752046; called by muse, mutect2
- TOR2A | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs866083524, COSV59121825; called by muse, mutect2
- DNAH11 | c.11961C>T p.I3987= | Silent (SNP) | VAF 3/42 reads (7%) | catalogued as COSV60952675; called by muse, mutect2
- PCDHA3 | c.1863G>A p.P621= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs782445556, COSV63540643; called by muse, mutect2
- PCK2 | c.243C>T p.G81= | Silent (SNP) | VAF 6/96 reads (6%) | catalogued as COSV53748533; called by muse, mutect2
- POM121L12 | c.726C>A p.P242= | Silent (SNP) | VAF 8/77 reads (10%) | catalogued as COSV68692758; called by muse, mutect2, varscan2
- TOX4 | c.1209C>T p.G403= | Silent (SNP) | VAF 7/192 reads (4%) | catalogued as rs1199326155, COSV99398294; called by muse, mutect2
- TTN | c.10360+4746A>T | Intron (SNP) | VAF 10/156 reads (6%) | catalogued as COSV59971623, COSV60002689; called by muse, mutect2
